Gene-level copy-number profile of tumor specimen HCM-CSHL-0177-C25-01B from HCMI case HCM-CSHL-0177-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 64.1 years (23,399 days).
Specimen HCM-CSHL-0177-C25-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9b7713e0-c7ea-4841-be95-7d8fabed9235.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0177-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/23de7f38-6d21-426a-9999-a583da266751

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 2: 16,586; copy number 3: 194; copy number 4: 34,183; copy number 5: 4,120; copy number 6: 3,104; copy number 7: 114; copy number 9: 85; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,994,139–22,128,103, 6 genes (within-gene range 0–2): CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 86 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:200,780,495–200,812,170, 1 gene, copy number 11 (within-gene range 4–11): BZW1-AS1.
- chr7:38,269,491–38,300,322, 6 genes, copy number 9 (within-gene range 4–9): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr14:21,887,857–22,501,663, 78 genes, copy number 9 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 9: TRAC.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
